Gene-level copy-number profile of tumor specimen TCGA-V1-A8MG-01A from TCGA case TCGA-V1-A8MG, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A8MG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.0438eeab-14dc-4974-b729-69a96ba2f838.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-V1-A8MG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 351 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c6b5b666-950d-402d-8094-641dce9e9ea4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3,826; copy number 1: 10,235; copy number 2: 43,802; copy number 3: 1,028; copy number 4: 316; copy number 5: 1,065.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-V1-A8MG-01A-11D-A363-01): tumor purity 0.29, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1,439 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:209,900,923–210,171,389, 1 gene (within-gene range 0–2): SYT14.
- chr1:210,231,456–237,951,536, 586 genes (broad region; genes not listed).
- chr1:238,777,049–241,364,054, 37 genes: MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1, AL356361.3, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA, AL365184.2, AL365184.1, THAP12P8, RGS7, RFKP1, HNRNPA1P42, AL590682.1, MIR3123, AL592076.1, AL359764.1.
- chr2:64,450,096–64,461,381, 2 genes (within-gene range 0–1): AC008074.1, LGALSL.
- chr6:30,451,139–30,494,194, 5 genes: AL662873.1, TMPOP1, SUCLA2P1, RANP1, HLA-E.
- chr6:86,729,708–122,211,811, 460 genes (within-gene range 0–1) (broad region; genes not listed).
- chr8:13,536,029–31,598,204, 347 genes (broad region; genes not listed).
- chr8:31,827,238–31,840,709, 1 gene: AC068931.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,065 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:69,851,148–139,508,971, 974 genes, copy number 5 (broad region; genes not listed).
- chr14:105,785,505–106,318,236, 91 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,688. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
